Somatic mutation profile of tumor specimen MP2PRT-PATHFL-TMP1-A (aliquot MP2PRT-PATHFL-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATHFL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,144 days).
Specimen MP2PRT-PATHFL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68bad658-3736-4936-a052-6512df44f7ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATHFL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATHFL-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f5ec32d-0d5a-4c36-ad20-539bec938260

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO2 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 110/249 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs779868128; called by muse, mutect2, varscan2
- HHIPL1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 96/431 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs768728552; called by muse, mutect2, varscan2
- NEBL | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV65799568; called by muse, mutect2
- SRCAP | c.3079C>T p.P1027S | Missense Mutation (SNP) | VAF 31/657 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV52670377; called by muse, mutect2
- ZNFX1 | c.270C>G p.D90E | Missense Mutation (SNP) | VAF 140/466 reads (30%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.001); catalogued as COSV65573231; called by muse, mutect2, varscan2
- AACS | c.756G>T p.K252N | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.34); called by muse, mutect2
- ADGRB3 | c.2280T>G p.F760L | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, varscan2
- ASB12 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 35/567 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- BTG1 | c.307_308insTGGCC p.T103Mfs*43 | Frame Shift Ins (INS) | VAF 52/301 reads (17%) | called by mutect2, pindel, varscan2
- EPPK1 | c.4429T>C p.Y1477H | Missense Mutation (SNP) | VAF 54/555 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR179 | c.3308G>A p.R1103K (on ENST00000621958; = p.R1102K on NM_001004334.4) | Missense Mutation (SNP) | VAF 61/565 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TBATA | c.914G>T p.C305F | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.014); called by muse, mutect2
- CNTNAP5 | c.2133A>T p.G711= | Silent (SNP) | VAF 92/335 reads (27%) | catalogued as COSV101443118; called by muse, mutect2, varscan2
- NBEAL2 | c.5943C>T p.F1981= | Silent (SNP) | VAF 18/556 reads (3%) | catalogued as COSV52754030; called by muse, mutect2
- NR0B1 | c.327C>T p.C109= | Silent (SNP) | VAF 57/732 reads (8%) | catalogued as CM013587, COSV66763873, COSV66764868; called by muse, mutect2
- RBM10 | c.1653G>A p.P551= | Silent (SNP) | VAF 46/540 reads (9%) | catalogued as COSV61311579; called by muse, mutect2
- RRAGA | c.798C>T p.F266= | Silent (SNP) | VAF 11/308 reads (4%) | called by muse, mutect2
- SLC9A4 | c.1101C>T p.F367= | Silent (SNP) | VAF 26/370 reads (7%) | catalogued as COSV99763506; called by muse, mutect2
- SMPDL3A | c.1155G>A p.P385= | Silent (SNP) | VAF 22/210 reads (10%) | catalogued as rs770221714, COSV100868659; called by muse, mutect2, varscan2
- TMX3 | c.15G>A p.K5= | Silent (SNP) | VAF 32/492 reads (7%) | catalogued as rs867506615, COSV55187030; called by muse, mutect2
- CNNM2 | c.-26G>C | 5'UTR (SNP) | VAF 68/521 reads (13%) | called by muse, mutect2, varscan2
